CCDI case PBCRBC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/63adc888-1404-4887-9105-4cddc2a33b39

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 0.6 years (236 days).

Biospecimens (2 samples)
- Sample 0DX7EW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX7FU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
